Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6959, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6959-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

- (A) RIGHT NECK DISSECTION, LEVELS I-V:
Twenty-eight lymph nodes, no tumor present (0/6 level I; 0/5 level II; 0/2 level III; 0/10 level IV; 0/5 level V).
Submandibular salivary gland with focal chronic inflammation and squamous metaplasia of ductal epithelium.
- (B) GLOSSAL MANDIBULAR SULCUS:
Squamous mucosa with focal mild dysplasia.
No tumor present.
- (C) GLOSSAL PHARYNGEAL SULCUS:
Skeletal muscle with minor salivary glands and segment of nerve, no tumor present.
- (D) PARTIAL GLOSSECTOMY:
INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA OF THE TONGUE (1.7 CM THICK). (SEE COMMENT)
SQUAMOUS CARCINOMA IN SITU.
Margins of resection submitted separately (specimens B, C, E, and F).
- (E) ANTERIOR TONGUE:
Squamous mucosa and underlying skeletal muscle, no tumor present.
- (F) DORSUM OF TONGUE:
Squamous mucosa and underlying skeletal muscle, no tumor present.
- (G) LYMPH NODE, RIGHT NECK:
One lymph node, no tumor present.
- (H) TEETH:
Teeth, gross diagnosis only.

Entire report and diagnosis completed by: [REDACTED]

Report released by: [REDACTED]

COMMENT

No perineural or lymphovascular invasion is identified.

GROSS DESCRIPTION

- (A) RIGHT NECK DISSECTION, LEVELS I-V - Soft tissue including fibroadipose tissue, lymph nodes and salivary gland measure in toto approximately 10.0 x 6.5 x 2.0 cm. The specimen has been divided into levels I-V. Level I includes a salivary gland (5.5 x 2.5 x 2.5 cm). Sections reveal no focal lesions. Lymph nodes in level I range from 0.5 to 1.8 cm in greatest dimension.
Lymph nodes in level II range from 0.8 to 2.8 cm.
Possible lymph nodes in level III measure 1.2 and 1.5 cm in greatest dimension.
Lymph nodes in level IV range from 0.4 to 3.8 cm.
Lymph nodes in level V range from 0.8 to 1.1 cm.

[page 2 of 2]
SECTION CODE: Level I: A1-A2, salivary gland; A3-A4, one lymph node section; A5, one lymph node bisected; A6-A8, one lymph node bisected in each cassette; A9-A10, one lymph node in each cassette; level II: A11-A12, one lymph node; A13-A14, one lymph node in each cassette; A15-A16, two lymph nodes in each cassette; level III: A17-A18, one lymph node in each cassette; level IV: A19-A20, two lymph nodes in each cassette; A21-A25, one lymph node in each cassette; A26-A28, one lymph node sectioned; level V: A29, two lymph nodes; A30-A32, one lymph node in each cassette. [REDACTED]

(B) GLOSSAL MANDIBULAR SULCUS - A fragment of pink-tan soft tissue, partially covered by mucosa (2.5 x 0.5 x 0.4 cm), is submitted entirely for frozen section in block B. [REDACTED]

*FS/DX: FOCAL MILD SQUAMOUS DYSPLASIA, NO TUMOR PRESENT. [REDACTED]

(C) GLOSSAL PHARYNGEAL SULCUS - Two fragments of pink-tan soft tissue are partially covered by mucosa together measuring 2.0 x 0.5 x 0.5 cm. All tissue is submitted in block B for frozen section. [REDACTED]

*FS/DX: SEGMENT OF NERVE, NO TUMOR PRESENT. SKELETAL MUSCLE WITH MINOR SALIVARY GLANDS, NO TUMOR PRESENT. [REDACTED]

(D) PARTIAL GLOSSECTOMY - A partial glossectomy has overall measurements of 7.0 x 5.5 x 3.0 cm. On the lateral gingival aspect of the specimen, is a large 4.0 x 3.0 x 1.0 cm fungating and ulcerated mass. The lesion invades up to 1.0 cm in one area with a smooth nodule extending to the middle of the specimen. Margins of resection appear uninvolved grossly. The specimen is submitted in a serial manner from inferior to anterior in D1-D17 including mucosa and adjacent tumor. [REDACTED]

(E) ANTERIOR TONGUE - A fragment of rubbery, pink-tan soft tissue (0.9 x 0.5 x 0.5 cm), is entirely submitted in block E for frozen section. BS/ymb

*FS/DX: TONGUE, NO TUMOR PRESENT. [REDACTED]

(F) DORSUM OF TONGUE - A fragment of rubbery, tan tissue (1.5 x 1.0 x 0.5 cm in greatest dimension) is submitted entirely, in cassette F for frozen section. [REDACTED]

*FS/DX: TONGUE, NO TUMOR PRESENT. [REDACTED]

(G) LYMPH NODE, RIGHT NECK - The specimen consists of a 0.3 x 0.2 x 0.2 cm tan fragment, entirely submitted in G. [REDACTED]

(H) TEETH - Twenty-four teeth and some small fragments of bone aggregating to 8.5 x 3.5 x 1.0 cm. The teeth consist of a mixture of molar and incisor teeth. A silver crown is noted on one molar and numerous silver fillings are noted within the other teeth. [REDACTED]

Source: NCI Genomic Data Commons file 2f21bd92-1c44-4506-a8d1-9be391eaaf20 (TCGA-CV-6959.3D9C7ECC-3495-4A7D-88A6-E4E448BF5998.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).